Surgical pathology report (de-identified scan), TCGA case TCGA-AF-3400, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-3400-01A (Primary Tumor).

[page 1 of 3]
TCGA-AF-3400

SPECIMEN

- A. Peritoneal implant
- B. Rectosigmoid colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectal cancer.

FROZEN SECTION DIAGNOSIS

Peritoneal implant, biopsy: Negative for malignancy.

GROSS DESCRIPTION

A. The specimen is received unfixed, labeled "perineal implant", and consists of a piece of yellow adipose tissue, measuring 1 x 1 x 0.3 cm. There is some nodularity by palpation. The largest nodule measures 0.3 cm. in diameter. A portion of the specimen is taken for frozen section diagnosis, as requested.

B. The specimen is received unfixed, labeled "rectosigmoid colon on the lid only", and consists of a segment of large bowel, measuring 23 cm. in length and 2.7 cm. in diameter. There is attached pericolic fat, measuring 13 x 20 x approximately 4 cm. There is a palpable mass in the specimen. The perineal reflection is either not present or is right near one stapled edge of the specimen. The bowel was opened with a single longitudinal incision.

There is a fungating tan mucosal tumor in the lumen, measuring 3.7 x 4.2 x 2.5 cm. The tumor is 3 cm. from the nearest margin of resection. Also identified on initial gross examination are two mucosal polyps. One is 0.4 cm. in diameter and is 1 cm. from the near margin of resection. There is another more sessile polyp, measuring 0.4 cm. in diameter that is 0.5 cm. from the near margin of resection. Additional polyps, measuring 0.3, 0.3, 0.2, 0.3 and 0.2 cm., are present. These are between the tumor and the far margin of resection. Portions of the specimen are taken for research purposes. There are no sections after fixation and

[page 2 of 3]
GROSS DESCRIPTION
clearing.

Block summary: 1,2 margins of resection; 3-5 polyps; 6-10 tumor;
11-23 lymph nodes.

MICROSCOPIC DESCRIPTION

A. Benign fibrofatty connective tissue is present.

B.

Histologic type: Mucinous type colonic adenocarcinoma. Some
signet

ring cells are present.

Histologic grade: Grade 2 out of 3

Tumor size: 4.2 x 3.7 x 2.5 cm

Distance to nearest margin: 3 cm

Level of penetration: Carcinoma invades through the muscularis
propria into pericolic soft tissue

Margins of resection: Negative for malignancy.

Vascular invasion: Absent

Host response: Mild chronic inflammation

Regional lymph nodes: There is no evidence of malignancy in any of
32 pericolic lymph nodes

Non-lymph node pericolic tumor: Absent

MSI probability: 3%

pTNM stage: T3 N0

Other findings: One lymph node has a necrotizing granuloma in it.

Special stains for acid fast bacteria and fungi are negative.

The polyps are hyperplastic type.

Antibody	Results	Comment
----------	---------	---------

[page 3 of 3]
MICROSCOPIC DESCRIPTION

AE1-AE3 Negative

Paraffin sections; 10% neutral buffered formalin

[A few of the antibodies used in our laboratory may be classified
as
analyte specific reagents. These antibodies are monitored and
controlled in our laboratory and their performance for in vitro
diagnosis is well described in the medical literature. They have
not been cleared or approved by the FDA.]

3,5,17x2,20

DIAGNOSIS

- A. Peritoneal implant, biopsy: Negative for malignancy
- B. Rectosigmoid colon, resection: Mucinous carcinoma, grade 2 out
of 3.

Hyperplastic polyps.

Note: Carcinoma invades into pericolic soft tissue. There is no
evidence of malignancy in any of 32 pericolic lymph nodes.

--- End Of Report ---

Source: NCI Genomic Data Commons file e3496129-6de2-45c1-8712-fcab97050959 (TCGA-AF-3400.E260E29C-B356-4687-A678-619D14A97176.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).